CCDI case PBBPPA — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/42c7ba0b-1552-4186-8027-6ec81ebbb428

Demographics
Sex at birth: female; Race: white; Vital status: Alive.

Diagnoses (1)
1. Dysembryoplastic neuroepithelial tumor: ICD-O-3 morphology code: 9413/0; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 11.8 years (4,299 days).

Biospecimens (3 samples)
- Sample 0DT1ZT: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DT20I: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DT20Q: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
